Somatic mutation profile of tumor specimen ALCH-B3IF-TTP1-A (aliquot ALCH-B3IF-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3IF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 41.6 years (15,184 days).
Specimen ALCH-B3IF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31d328c0-c115-43af-93a6-f2b53e9c8c26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3IF-NB1-A (Blood Derived Normal), aliquot ALCH-B3IF-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7fbfab6-786d-44ac-86d1-59ab663ae3b0

The open-access MAF lists 447 somatic variants for this specimen: 314 protein-altering or splice-affecting, 83 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 270, Silent 83, Intron 23, Nonsense Mutation 21, 3'UTR 10, RNA 8, Splice Site 8, Frame Shift Del 8, 5'Flank 4, Splice Region 3, 3'Flank 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 40/169 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 73/298 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.1991A>C p.H664P | Missense Mutation (SNP) | VAF 56/389 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as rs149938879; called by muse, mutect2, varscan2
- ABCA9 | c.308G>T p.R103I | Missense Mutation (SNP) | VAF 21/205 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV100383131; called by muse, mutect2, varscan2
- ABCD2 | c.1726A>G p.T576A | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs1229686213; called by muse, mutect2
- ACTR10 | c.1148G>T p.R383L | Missense Mutation (SNP) | VAF 60/328 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV54297362; called by muse, mutect2, varscan2
- ADAMTS3 | c.217G>T p.V73L | Missense Mutation (SNP) | VAF 59/339 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.36); catalogued as COSV99710121; called by muse, mutect2, varscan2
- ARF5 | c.455C>A p.T152K | Missense Mutation (SNP) | VAF 65/528 reads (12%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs749643254, COSV99133512, COSV99134006; called by muse, mutect2, varscan2
- ASXL3 | c.4471G>T p.V1491F | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); catalogued as rs751537958, COSV99326181; called by muse, mutect2, varscan2
- ATP2B3 | c.3509G>A p.R1170H | Missense Mutation (SNP) | VAF 97/397 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs111317380, COSV54843333; called by muse, mutect2, varscan2
- ATP2C1 | c.847G>T p.V283F | Missense Mutation (SNP) | VAF 56/517 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV60760419; called by muse, mutect2, varscan2
- B4GALT6 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 65/473 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52703301; called by muse, mutect2, varscan2
- C10orf71 | c.3818C>A p.T1273N | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs779022484; called by muse, mutect2, varscan2
- CALCRL | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 91/363 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as rs751001936; called by muse, mutect2, varscan2
- CGNL1 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 20/291 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs772375615, COSV55563697; called by muse, mutect2
- CNTNAP2 | c.2263G>A p.D755N | Missense Mutation (SNP) | VAF 184/800 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.803); catalogued as COSV62178085; called by muse, mutect2, varscan2
- COL4A1 | c.1037G>C p.R346T | Missense Mutation (SNP) | VAF 40/570 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.077); catalogued as rs774678188; called by muse, mutect2
- COL6A2 | c.2290del p.H764Tfs*23 | Frame Shift Del (DEL) | VAF 104/658 reads (16%) | catalogued as COSV100153980; called by mutect2, pindel, varscan2
- COL9A1 | c.2704G>C p.E902Q | Missense Mutation (SNP) | VAF 90/630 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.959); catalogued as COSV57882350; called by muse, mutect2, varscan2
- CSMD1 | c.4666G>A p.E1556K (on ENST00000520002; = p.E1555K on NM_033225.6) | Missense Mutation (SNP) | VAF 64/354 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs986723587, COSV59289351; called by muse, mutect2, varscan2
- CSMD2 | c.2164C>G p.L722V | Missense Mutation (SNP) | VAF 43/531 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV99590336; called by muse, mutect2
- DCAF12L1 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 54/780 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as COSV64422190; called by muse, mutect2
- DLD | c.595A>G p.T199A | Missense Mutation (SNP) | VAF 77/388 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1221966658; called by muse, mutect2, varscan2
- DLGAP2 | c.1580G>T p.C527F | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1219587961; called by muse, mutect2, varscan2
- DPYS | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 203/800 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1243453247; called by muse, mutect2, varscan2
- EFCAB6 | c.139+1G>T p.X47_splice | Splice Site (SNP) | VAF 32/190 reads (17%) | catalogued as COSV53060637; called by muse, mutect2, varscan2
- ERBB4 | c.2668G>T p.E890* | Nonsense Mutation (SNP) | VAF 99/630 reads (16%) | catalogued as COSV61505131, COSV61509270; called by muse, mutect2, varscan2
- FER1L6 | c.1655C>A p.A552D | Missense Mutation (SNP) | VAF 90/409 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.018); catalogued as rs1312295422; called by muse, mutect2, varscan2
- FMN2 | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 57/247 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV100144512; called by muse, mutect2, varscan2
- FOXA2 | c.1283C>T p.T428M (on ENST00000377115 / NM_153675.3; = p.T434M on NM_021784.5) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV101008442; called by muse, mutect2, varscan2
- GNB3 | c.385C>A p.R129S | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV99301955; called by muse, mutect2, varscan2
- GRIA4 | c.125C>A p.T42N | Missense Mutation (SNP) | VAF 32/432 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV56895177, COSV56923636; called by muse, mutect2
- GUCY1A1 | c.1588G>T p.D530Y | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56649597; called by muse, mutect2, varscan2
- GUCY2C | c.2601+6C>A | Splice Region (SNP) | VAF 25/219 reads (11%) | catalogued as COSV53791986; called by muse, mutect2, varscan2
- HACE1 | c.2377G>T p.V793L | Missense Mutation (SNP) | VAF 36/670 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as COSV53505313; called by muse, mutect2
- IFNA2 | c.279G>T p.K93N | Missense Mutation (SNP) | VAF 83/512 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV66505993; called by muse, mutect2, varscan2
- IL13RA2 | c.743G>C p.R248P | Missense Mutation (SNP) | VAF 29/574 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99683222; called by muse, mutect2
- IPO11 | c.982G>T p.V328F | Missense Mutation (SNP) | VAF 427/668 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs1346863807; called by muse, mutect2, varscan2
- IRS4 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 75/748 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs1396380497; called by muse, mutect2, varscan2
- JAKMIP2 | c.1225-2A>T p.X409_splice | Splice Site (SNP) | VAF 141/658 reads (21%) | catalogued as COSV99509549; called by muse, mutect2, varscan2
- KAZN | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs768614439, COSV100748149; called by muse, mutect2
- KCP | c.1244C>A p.P415H (on ENST00000620378; = p.P472H on NM_001366122.1) | Missense Mutation (SNP) | VAF 39/238 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as rs1396247918; called by muse, varscan2
- KLHL1 | c.637G>T p.D213Y | Missense Mutation (SNP) | VAF 56/636 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1228325275; called by muse, mutect2
- KLRG2 | c.1005G>T p.Q335H | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100572490; called by muse, mutect2, varscan2
- LUM | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 28/493 reads (6%) | catalogued as COSV57127483, COSV57127798; called by muse, mutect2
- MINDY2 | c.1015G>A p.V339I | Missense Mutation (SNP) | VAF 51/305 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as COSV57506873; called by muse, mutect2, varscan2
- MMP27 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 37/297 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52782518; called by muse, mutect2, varscan2
- MRPL16 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 66/511 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs774234238, COSV55701052; called by muse, mutect2, varscan2
- NBEA | c.6807-1G>T p.X2269_splice | Splice Site (SNP) | VAF 24/167 reads (14%) | catalogued as COSV59830816; called by muse, mutect2, varscan2
- NLGN4X | c.15G>T p.Q5H | Missense Mutation (SNP) | VAF 67/407 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.033); catalogued as COSV99322955; called by muse, mutect2, varscan2
- NOC4L | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 55/309 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs748251112; called by muse, mutect2, varscan2
- NRXN2 | c.2170C>T p.R724W | Missense Mutation (SNP) | VAF 68/553 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs765856391, COSV99631981; called by muse, mutect2, varscan2
- OARD1 | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 45/301 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.358); catalogued as rs1220222275; called by muse, mutect2, varscan2
- OIT3 | c.220T>A p.C74S | Missense Mutation (SNP) | VAF 54/256 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs917844549; called by muse, mutect2, varscan2
- OR2M5 | c.280A>G p.M94V | Missense Mutation (SNP) | VAF 213/833 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs756348090; called by muse, mutect2, varscan2
- OR2T2 | c.47C>G p.T16R | Missense Mutation (SNP) | VAF 259/2078 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs760821810, COSV61618580; called by muse, mutect2, varscan2
- OR4L1 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs1420434986, COSV59849654; called by muse, varscan2
- OR4P4 | c.408G>T p.R136S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV58923491; called by muse, mutect2, varscan2
- OR52N4 | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 111/493 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as rs373532134; called by muse, mutect2, varscan2
- OR56A3 | c.712G>T p.V238L | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.092); catalogued as rs192910465; called by muse, mutect2, varscan2
- OR5H14 | c.678G>T p.L226F | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.37); PolyPhen probably damaging (1); catalogued as COSV71194273; called by muse, mutect2, varscan2
- PCDH11X | c.2440C>G p.L814V | Missense Mutation (SNP) | VAF 73/848 reads (9%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as COSV53472082; called by muse, mutect2
- PCDH17 | c.3125C>A p.A1042E | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV64973464, COSV64975027; called by muse, mutect2, varscan2
- PCDHA6 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 235/1196 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.753); catalogued as rs1554132154; called by muse, mutect2, varscan2
- PLVAP | c.831C>A p.S277R | Missense Mutation (SNP) | VAF 78/225 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV53087737; called by muse, mutect2, varscan2
- PNPLA5 | c.691C>A p.P231T | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs140390340; called by muse, mutect2, varscan2
- POTEH | c.405G>T p.M135I | Missense Mutation (SNP) | VAF 126/1362 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as COSV58886982; called by muse, varscan2
- POTEH | c.406G>T p.G136C | Missense Mutation (SNP) | VAF 130/1350 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); catalogued as COSV58879567; called by muse, varscan2
- PPIL3 | c.179G>T p.G60V (on ENST00000392283 / NM_130906.3; = p.G64V on NM_032472.4) | Missense Mutation (SNP) | VAF 100/384 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148778524; called by muse, mutect2, varscan2
- PPP1R3A | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 56/596 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV99491930; called by muse, mutect2
- PRG4 | c.154C>A p.H52N | Missense Mutation (SNP) | VAF 82/1308 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1231629287; called by muse, mutect2
- PRG4 | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 157/911 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs780042661; called by muse, mutect2, varscan2
- PTCD2 | c.778A>T p.I260F | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV57339015; called by muse, mutect2
- RBMXL3 | c.1513G>A p.G505R | Missense Mutation (SNP) | VAF 28/273 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs782181101, COSV57754630; called by muse, mutect2, varscan2
- RTP1 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 35/281 reads (12%) | catalogued as COSV56618060; called by muse, mutect2, varscan2
- SAGE1 | c.2356del p.V786* | Frame Shift Del (DEL) | VAF 65/443 reads (15%) | catalogued as COSV61012319, COSV61014564; called by mutect2, pindel, varscan2
- SDK1 | c.4402G>A p.V1468I | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs910136081, COSV67370497; called by muse, mutect2
- SECTM1 | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as COSV53940878; called by muse, mutect2, varscan2
- SI | c.231C>A p.C77* | Nonsense Mutation (SNP) | VAF 26/412 reads (6%) | catalogued as rs776059197; called by muse, mutect2
- SLC17A5 | c.1268G>T p.G423V | Missense Mutation (SNP) | VAF 134/940 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63288221; called by muse, mutect2, varscan2
- SLC17A7 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs532058755, COSV55550447; called by muse, mutect2, varscan2
- SLCO5A1 | c.1064C>G p.A355G | Missense Mutation (SNP) | VAF 21/368 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.134); catalogued as COSV99479437; called by muse, mutect2
- SLITRK1 | c.888G>T p.E296D | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV65674732, COSV65677259; called by muse, mutect2
- SMARCA4 | c.1761G>T p.K587N | Missense Mutation (SNP) | VAF 94/339 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV100759024; called by muse, mutect2, varscan2
- SOCS5 | c.1334G>T p.C445F | Missense Mutation (SNP) | VAF 156/590 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.839); catalogued as COSV60603741; called by muse, mutect2, varscan2
- SORCS1 | c.3040G>T p.G1014W | Missense Mutation (SNP) | VAF 34/327 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53853752, COSV99543007; called by muse, mutect2
- SPEG | c.8974T>C p.F2992L | Missense Mutation (SNP) | VAF 125/381 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs1371333008; called by muse, mutect2, varscan2
- STYXL2 | c.3163C>A p.P1055T | Missense Mutation (SNP) | VAF 83/322 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as COSV99608976; called by muse, mutect2, varscan2
- TBX18 | c.644A>T p.D215V | Missense Mutation (SNP) | VAF 36/421 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767464678; called by muse, mutect2
- TCF4 | c.1291G>T p.G431C | Missense Mutation (SNP) | VAF 117/650 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752176058; called by muse, mutect2, varscan2
- TCP11L2 | c.1427T>C p.L476P | Missense Mutation (SNP) | VAF 76/434 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs771425977; called by muse, mutect2, varscan2
- TEX15 | c.7483G>T p.D2495Y (on ENST00000256246; = p.D2878Y on NM_001350162.2) | Missense Mutation (SNP) | VAF 66/247 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs769647475, COSV56355484; called by muse, mutect2, varscan2
- THSD1 | c.766G>T p.V256L | Missense Mutation (SNP) | VAF 40/560 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs765042863; called by muse, mutect2
- TIMD4 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 42/384 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV50859056; called by mutect2, varscan2
- TLL1 | c.314G>T p.R105L | Missense Mutation (SNP) | VAF 124/770 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.09); catalogued as COSV50322060; called by muse, mutect2, varscan2
- TLL1 | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 126/571 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.676); catalogued as rs1260069934; called by muse, mutect2, varscan2
- TMC3 | c.3044G>A p.R1015Q | Missense Mutation (SNP) | VAF 49/461 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); catalogued as COSV63922835; called by muse, mutect2, varscan2
- TMEM74 | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 67/536 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52463990; called by muse, mutect2, varscan2
- TSC22D2 | c.595G>T p.G199W | Missense Mutation (SNP) | VAF 84/579 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV62622911; called by muse, mutect2, varscan2
- TSPOAP1 | c.3626G>A p.R1209Q | Missense Mutation (SNP) | VAF 108/498 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs760194696, COSV52117358; called by muse, mutect2, varscan2
- TTN | c.36266C>G p.P12089R (on ENST00000591111; = p.P4665R on NM_003319.4) | Missense Mutation (SNP) | VAF 62/729 reads (9%) | PolyPhen probably damaging (0.999); catalogued as COSV60440706; called by muse, mutect2
- TTN | c.31099G>C p.V10367L (on ENST00000591111; = p.V9440L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/362 reads (8%) | PolyPhen benign (0.02); catalogued as COSV60107714; called by muse, mutect2
- UTP14C | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 38/610 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1020247153; called by muse, mutect2
- VPS13B | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs138271331; called by muse, mutect2, varscan2
- ZFHX4 | c.4801G>C p.A1601P | Missense Mutation (SNP) | VAF 160/668 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV50731042; called by muse, mutect2, varscan2
- ABCA5 | c.1268G>T p.G423V | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ABCD2 | c.2094A>T p.E698D | Missense Mutation (SNP) | VAF 78/819 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.046); called by muse, mutect2
- AC098582.1 | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 74/424 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AC100868.1 | c.1169C>A p.T390N | Missense Mutation (SNP) | VAF 84/582 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- AGO1 | c.1226G>T p.R409L | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); called by muse, varscan2
- AKAP6 | c.3435G>T p.Q1145H | Missense Mutation (SNP) | VAF 79/480 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AKT2 | c.1029G>T p.M343I | Missense Mutation (SNP) | VAF 170/781 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- AL592490.1 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 29/379 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.703); called by muse, mutect2
- ALAS2 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- ALDH1A1 | c.1396T>C p.F466L | Missense Mutation (SNP) | VAF 100/602 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ALLC | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 21/126 reads (17%) | called by muse, mutect2, varscan2
- AMER1 | c.1292C>A p.P431Q | Missense Mutation (SNP) | VAF 69/480 reads (14%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ANKRD20A4P | c.1984G>T p.E662* | Nonsense Mutation (SNP) | VAF 20/168 reads (12%) | called by mutect2, varscan2
- ANKRD30B | c.329T>G p.L110R | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ANXA8 | c.329G>C p.G110A | Missense Mutation (SNP) | VAF 71/819 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- AQP12A | c.145G>T p.G49W | Missense Mutation (SNP) | VAF 172/798 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ARFGEF2 | c.4654A>C p.K1552Q | Missense Mutation (SNP) | VAF 83/1158 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.411); called by muse, mutect2
- ARHGAP11A | c.2324C>T p.S775L | Missense Mutation (SNP) | VAF 47/313 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BRINP2 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 56/730 reads (8%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.056); called by muse, mutect2
- BRINP2 | c.332C>A p.P111Q | Missense Mutation (SNP) | VAF 49/574 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2
- BTN3A2 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 58/425 reads (14%) | called by muse, mutect2, varscan2
- C10orf53 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 131/738 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.738); called by muse, varscan2
- C22orf42 | c.54C>A p.D18E | Missense Mutation (SNP) | VAF 72/537 reads (13%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- CCDC103 | c.81A>T p.K27N | Missense Mutation (SNP) | VAF 81/414 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CCDC142 | c.1484_1498del p.K495_Q499del (on ENST00000393965 / NM_001365575.2; = p.K488_Q492del on NM_032779.4) | In Frame Del (DEL) | VAF 16/140 reads (11%) | called by mutect2, pindel
- CCDC168 | c.15247C>T p.L5083F | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); called by muse, mutect2
- CD109 | c.856-1G>T p.X286_splice | Splice Site (SNP) | VAF 22/144 reads (15%) | called by muse, mutect2, varscan2
- CENPE | c.3815A>T p.E1272V | Missense Mutation (SNP) | VAF 86/335 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- CFAP54 | c.5090G>T p.S1697I | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- CFAP74 | c.3333G>T p.K1111N | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.218); called by muse, varscan2
- CHD7 | c.6201G>T p.Q2067H | Missense Mutation (SNP) | VAF 210/685 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CHL1 | c.1135G>T p.D379Y (on ENST00000397491 / NM_001253387.1; = p.D395Y on NM_006614.4) | Missense Mutation (SNP) | VAF 51/260 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- CKAP5 | c.5544+1G>T p.X1848_splice (on ENST00000529230 / NM_001008938.4; = p.X1788_splice on NM_014756.3) | Splice Site (SNP) | VAF 18/188 reads (10%) | called by muse, mutect2
- CLCN1 | c.2725C>A p.L909M | Missense Mutation (SNP) | VAF 72/573 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- COL11A1 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 65/1076 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- COL4A1 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 45/508 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL4A6 | c.299C>A p.P100H | Missense Mutation (SNP) | VAF 34/518 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CPN2 | c.770C>A p.P257Q | Missense Mutation (SNP) | VAF 55/319 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- CRB1 | c.1102G>C p.G368R | Missense Mutation (SNP) | VAF 264/968 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CSMD2 | c.9886G>A p.V3296M | Missense Mutation (SNP) | VAF 78/610 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- CTH | c.476C>A p.P159H | Missense Mutation (SNP) | VAF 85/957 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CTNND2 | c.1154T>A p.L385H | Missense Mutation (SNP) | VAF 84/570 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CTTNBP2 | c.180G>T p.E60D | Missense Mutation (SNP) | VAF 79/398 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, varscan2
- DGKK | c.3559G>T p.E1187* | Nonsense Mutation (SNP) | VAF 68/580 reads (12%) | called by muse, mutect2, varscan2
- DIP2C | c.1589A>C p.Y530S | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DLGAP2 | c.1338G>T p.E446D | Missense Mutation (SNP) | VAF 71/377 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAAF2 | c.1393G>T p.G465* | Nonsense Mutation (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2
- DNAH11 | c.7177G>T p.V2393L | Missense Mutation (SNP) | VAF 156/1095 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DNAH8 | c.8461G>C p.V2821L | Missense Mutation (SNP) | VAF 84/514 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- DOCK3 | c.1705A>T p.K569* | Nonsense Mutation (SNP) | VAF 36/370 reads (10%) | called by muse, mutect2, varscan2
- DPYS | c.922C>G p.P308A | Missense Mutation (SNP) | VAF 139/508 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- DUSP15 | c.820G>T p.G274C | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- ELMO1 | c.1418C>A p.T473N | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.108); called by muse, mutect2
- EPHA5 | c.2794T>A p.L932M | Missense Mutation (SNP) | VAF 46/248 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ERN2 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 175/793 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- F2R | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 66/592 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM187A | c.38G>T p.W13L | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.01); called by mutect2, varscan2
- FAM205A | c.3473C>A p.A1158D | Missense Mutation (SNP) | VAF 80/431 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- FAM47C | c.2126C>A p.T709N | Missense Mutation (SNP) | VAF 38/824 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- FAM83F | c.1074G>T p.Q358H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.36); called by muse, mutect2
- FBXO7 | c.54G>C p.E18D | Missense Mutation (SNP) | VAF 89/618 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FLT1 | c.2823G>C p.K941N | Missense Mutation (SNP) | VAF 45/612 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.494); called by muse, mutect2
- FMO1 | c.1376T>A p.L459Q | Missense Mutation (SNP) | VAF 50/748 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- FMO2 | c.239dup p.N80Kfs*5 | Frame Shift Ins (INS) | VAF 49/291 reads (17%) | called by mutect2, pindel, varscan2
- FNDC8 | c.607G>A p.G203S | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- FOCAD | c.2248G>A p.V750M | Missense Mutation (SNP) | VAF 88/490 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FPR1 | c.292T>C p.C98R | Missense Mutation (SNP) | VAF 30/427 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- FRMD7 | c.1223C>A p.S408Y | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FRRS1 | c.90G>T p.Q30H | Missense Mutation (SNP) | VAF 69/510 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- FZD10 | c.939C>A p.F313L | Missense Mutation (SNP) | VAF 59/766 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GAB3 | c.1180G>T p.V394L | Missense Mutation (SNP) | VAF 74/301 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- GAB4 | c.434A>G p.Q145R | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0); called by mutect2, varscan2
- GABRA3 | c.1314C>A p.Y438* | Nonsense Mutation (SNP) | VAF 96/1108 reads (9%) | called by muse, mutect2
- GABRG3 | c.659A>T p.Q220L | Missense Mutation (SNP) | VAF 104/581 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, varscan2
- GABRQ | c.594C>A p.N198K | Missense Mutation (SNP) | VAF 36/524 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GBF1 | c.1841_1869del p.C614* (on ENST00000369983 / NM_001377137.1; = p.C613* on NM_004193.3) | Frame Shift Del (DEL) | VAF 70/358 reads (20%) | called by mutect2, pindel
- GDI1 | c.1211A>G p.Y404C | Missense Mutation (SNP) | VAF 139/896 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- GDPD5 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 39/317 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPX5 | c.352G>C p.G118R | Missense Mutation (SNP) | VAF 136/978 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GRIK2 | c.2401G>T p.G801C | Missense Mutation (SNP) | VAF 141/741 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GRIN2B | c.2396G>T p.G799V | Missense Mutation (SNP) | VAF 46/604 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GSTM2 | c.350A>T p.D117V | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2
- HDAC6 | c.886G>T p.G296C | Missense Mutation (SNP) | VAF 26/576 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HELZ | c.4316G>T p.R1439L | Missense Mutation (SNP) | VAF 26/348 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.091); called by muse, mutect2
- HTR2C | c.150C>A p.D50E | Missense Mutation (SNP) | VAF 128/593 reads (22%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- HTT | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- IFT88 | c.2288G>T p.S763I (on ENST00000319980 / NM_001318493.2; = p.S754I on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/339 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.181G>T p.G61W | Missense Mutation (SNP) | VAF 117/447 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGSF1 | c.3626G>T p.G1209V | Missense Mutation (SNP) | VAF 131/846 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KATNA1 | c.421G>T p.A141S | Missense Mutation (SNP) | VAF 42/404 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2
- KCNC2 | c.1206T>G p.Y402* | Nonsense Mutation (SNP) | VAF 23/189 reads (12%) | called by muse, mutect2, varscan2
- KCNK13 | c.231C>A p.H77Q | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- KCP | c.1246C>A p.P416T (on ENST00000620378; = p.P473T on NM_001366122.1) | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, varscan2
- KLF3 | c.442G>T p.V148L | Missense Mutation (SNP) | VAF 151/822 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- KMT2D | c.15392T>C p.M5131T | Missense Mutation (SNP) | VAF 163/1664 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); called by muse, mutect2
- KRT79 | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 36/408 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2
- L2HGDH | c.98G>T p.R33M | Missense Mutation (SNP) | VAF 119/639 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- LAMA4 | c.137A>T p.D46V | Missense Mutation (SNP) | VAF 94/569 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- LCE2A | c.47G>T p.C16F | Missense Mutation (SNP) | VAF 26/505 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); called by muse, mutect2
- LCOR | c.4029G>T p.K1343N | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2
- LRRC4C | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 46/395 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- LRRC8C | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 96/574 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LTBP4 | c.3794G>T p.C1265F (on ENST00000308370 / NM_001042544.1; = p.C1228F on NM_003573.2) | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- LUM | c.717C>A p.N239K | Missense Mutation (SNP) | VAF 28/496 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAGEC3 | c.845T>C p.V282A | Missense Mutation (SNP) | VAF 26/494 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.088); called by muse, mutect2
- MBD3L1 | c.66G>T p.L22F | Missense Mutation (SNP) | VAF 86/310 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MDFI | c.308A>T p.D103V | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MGAT4C | c.539C>G p.P180R | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPV17L | c.410A>T p.Q137L (on ENST00000396385 / NM_001128423.2; = p.T113= on NM_173803.4) | Missense Mutation (SNP) | VAF 72/445 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRPL42 | c.92G>T p.C31F | Missense Mutation (SNP) | VAF 21/428 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- MS4A12 | c.415-2A>T p.X139_splice | Splice Site (SNP) | VAF 30/439 reads (7%) | called by muse, mutect2
- MTUS2 | c.1529G>T p.R510M | Missense Mutation (SNP) | VAF 30/397 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2
- MUC12 | c.12250T>C p.Y4084H (on ENST00000379442; = p.Y3941H on NM_001164462.1) | Missense Mutation (SNP) | VAF 150/4476 reads (3%) | SIFT tolerated (1); called by muse, mutect2
- MUC17 | c.2514del p.T839Lfs*29 | Frame Shift Del (DEL) | VAF 38/288 reads (13%) | called by mutect2, varscan2
- MUC17 | c.10184G>T p.S3395I | Missense Mutation (SNP) | VAF 35/324 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NCAPD3 | c.2038G>T p.E680* | Nonsense Mutation (SNP) | VAF 24/191 reads (13%) | called by muse, mutect2, varscan2
- NID2 | c.1990T>G p.S664A | Missense Mutation (SNP) | VAF 118/645 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLGN1 | c.708A>T p.Q236H | Missense Mutation (SNP) | VAF 71/686 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); called by muse, mutect2
- NLGN4X | c.16G>T p.G6* | Nonsense Mutation (SNP) | VAF 68/405 reads (17%) | called by muse, mutect2, varscan2
- NRXN1 | c.3324C>A p.D1108E | Missense Mutation (SNP) | VAF 72/293 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUB1 | c.13G>C p.G5R | Missense Mutation (SNP) | VAF 70/319 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); called by muse, varscan2
- NXPE2 | c.1568dup p.I525Yfs*3 | Frame Shift Ins (INS) | VAF 42/295 reads (14%) | called by mutect2, pindel, varscan2
- NYAP1 | c.1546G>A p.G516R | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OLFM4 | c.641G>T p.R214L | Missense Mutation (SNP) | VAF 42/318 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- OR13G1 | c.302T>A p.F101Y | Missense Mutation (SNP) | VAF 107/349 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- OR1S1 | c.719G>T p.R240I | Missense Mutation (SNP) | VAF 50/569 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2
- OR51I2 | c.162C>G p.S54R | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, varscan2
- OR52E2 | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2, varscan2
- P2RX2 | c.941C>A p.T314N (on ENST00000343948 / NM_170683.4; = p.T242N on NM_012226.5) | Missense Mutation (SNP) | VAF 32/407 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.828); called by muse, mutect2
- PCLO | c.8190G>T p.L2730F | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHYHIPL | c.642T>A p.S214R | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by mutect2, varscan2
- PIEZO2 | c.2085C>A p.F695L | Missense Mutation (SNP) | VAF 33/545 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2
- PKD1L1 | c.3257G>T p.R1086I | Missense Mutation (SNP) | VAF 67/595 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLXNA1 | c.5633G>T p.R1878L | Missense Mutation (SNP) | VAF 28/283 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- PPDPFL | c.254A>T p.*85Lext*100 | Nonstop Mutation (SNP) | VAF 180/716 reads (25%) | called by muse, mutect2, varscan2
- PPIH | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 23/637 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- PRKN | c.922G>T p.G308* | Nonsense Mutation (SNP) | VAF 85/1002 reads (8%) | called by muse, mutect2
- PXDN | c.1061T>G p.L354R | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.19); called by muse, varscan2
- PXDN | c.1060C>A p.L354M | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- RASL11B | c.107T>C p.I36T | Missense Mutation (SNP) | VAF 114/266 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- RBP7 | c.125T>A p.V42E | Missense Mutation (SNP) | VAF 40/458 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2
- REG3A | c.77-2A>T p.X26_splice | Splice Site (SNP) | VAF 41/170 reads (24%) | called by muse, mutect2, varscan2
- RNF207 | c.628-8G>T | Splice Region (SNP) | VAF 92/360 reads (26%) | called by muse, mutect2, varscan2
- RNF8 | c.773G>A p.R258K | Missense Mutation (SNP) | VAF 57/354 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROBO4 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- RTP1 | c.441G>T p.E147D | Missense Mutation (SNP) | VAF 35/285 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- RYR2 | c.5193G>C p.E1731D | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RYR2 | c.8737G>T p.D2913Y | Missense Mutation (SNP) | VAF 32/634 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- RYR3 | c.1586G>C p.R529P | Missense Mutation (SNP) | VAF 44/276 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SASH1 | c.628-2A>T p.X210_splice | Splice Site (SNP) | VAF 56/370 reads (15%) | called by muse, mutect2, varscan2
- SBF1 | c.1748A>T p.K583M | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SBSN | c.65G>A p.W22* | Nonsense Mutation (SNP) | VAF 22/126 reads (17%) | called by muse, mutect2, varscan2
- SCP2D1 | c.382G>C p.A128P | Missense Mutation (SNP) | VAF 105/440 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEPTIN6 | c.266A>T p.Q89L | Missense Mutation (SNP) | VAF 136/522 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- SERPINA7 | c.425C>A p.P142Q | Missense Mutation (SNP) | VAF 103/752 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SERPINB2 | c.206C>G p.T69S | Missense Mutation (SNP) | VAF 59/523 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SETBP1 | c.929G>C p.G310A | Missense Mutation (SNP) | VAF 42/455 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- SF3B3 | c.2620G>A p.G874R | Missense Mutation (SNP) | VAF 87/448 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SI | c.2267A>T p.Y756F | Missense Mutation (SNP) | VAF 46/571 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- SIGLEC14 | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 142/515 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- SLC16A2 | c.431C>A p.A144E | Missense Mutation (SNP) | VAF 63/856 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2
- SLC6A5 | c.848del p.I283Kfs*7 | Frame Shift Del (DEL) | VAF 75/482 reads (16%) | called by mutect2, pindel, varscan2
- SLC9A9 | c.1831G>T p.A611S | Missense Mutation (SNP) | VAF 75/612 reads (12%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA31A6 | c.2014G>T p.G672C | Missense Mutation (SNP) | VAF 215/707 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SPATA48 | c.668T>G p.L223R | Missense Mutation (SNP) | VAF 78/592 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- SPEF2 | c.5054C>A p.P1685H | Missense Mutation (SNP) | VAF 125/391 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- STARD9 | c.2663G>A p.G888E | Missense Mutation (SNP) | VAF 84/426 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- STK11 | c.951del p.A318Hfs*18 | Frame Shift Del (DEL) | VAF 33/119 reads (28%) | called by mutect2, pindel, varscan2
- SULT1C4 | c.444T>G p.H148Q | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SYT1 | c.595C>A p.H199N | Missense Mutation (SNP) | VAF 14/293 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- TAF1 | c.677G>T p.G226V (on ENST00000373790 / NM_138923.4; = p.G247V on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/280 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TBC1D25 | c.766G>T p.D256Y | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.113); called by muse, mutect2
- TCF23 | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 190/687 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TDRD15 | c.4292C>T p.T1431I | Missense Mutation (SNP) | VAF 11/238 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.081); called by muse, mutect2
- TENM1 | c.5390T>A p.L1797H | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TENM1 | c.2225A>T p.E742V | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TGM1 | c.2199A>T p.L733F | Missense Mutation (SNP) | VAF 130/748 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- THSD4 | c.1294G>T p.E432* | Nonsense Mutation (SNP) | VAF 123/666 reads (18%) | called by muse, mutect2, varscan2
- THSD7A | c.4099A>C p.I1367L | Missense Mutation (SNP) | VAF 53/250 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, varscan2
- TIAM1 | c.4012G>T p.E1338* | Nonsense Mutation (SNP) | VAF 47/346 reads (14%) | called by muse, varscan2
- TLX1 | c.493G>T p.G165C | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- TMEM65 | c.98G>T p.C33F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); called by mutect2, varscan2
- TNN | c.2597G>T p.W866L | Missense Mutation (SNP) | VAF 37/617 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- TNXB | c.4476T>C p.T1492= (on ENST00000647633; = p.T1245= on NM_019105.8 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 14/96 reads (15%) | called by muse, varscan2
- TRAPPC2B | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 166/693 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRHDE | c.1540C>T p.Q514* | Nonsense Mutation (SNP) | VAF 68/459 reads (15%) | called by muse, mutect2, varscan2
- TRIM63 | c.18C>G p.S6R | Missense Mutation (SNP) | VAF 19/268 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2
- TRIM64C | c.1075del p.R359Efs*10 | Frame Shift Del (DEL) | VAF 95/526 reads (18%) | called by mutect2, pindel, varscan2
- TRMT12 | c.1126A>T p.T376S | Missense Mutation (SNP) | VAF 63/388 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRPC6 | c.1597A>T p.M533L | Missense Mutation (SNP) | VAF 144/859 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- TTN | c.39012G>T p.K13004N (on ENST00000591111; = p.K5580N on NM_003319.4) | Missense Mutation (SNP) | VAF 81/1362 reads (6%) | PolyPhen probably damaging (0.964); called by muse, mutect2
- UBE2H | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 43/436 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- UNC5D | c.2603C>G p.P868R | Missense Mutation (SNP) | VAF 44/459 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2
- VWA5B2 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- VWC2L | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- VWC2L | c.398C>A p.P133Q | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- XPNPEP2 | c.676C>A p.Q226K | Missense Mutation (SNP) | VAF 78/365 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZFHX4 | c.6049C>A p.P2017T | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, varscan2
- ZMAT1 | c.915del p.D306Mfs*15 | Frame Shift Del (DEL) | VAF 77/363 reads (21%) | called by mutect2, pindel, varscan2
- ZNF208 | c.3187G>T p.G1063C | Missense Mutation (SNP) | VAF 187/836 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF322 | c.1184C>A p.A395E | Missense Mutation (SNP) | VAF 79/1010 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); called by muse, mutect2
- ZNF366 | c.1011C>A p.H337Q | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2
- ZNF443 | c.1930A>T p.T644S | Missense Mutation (SNP) | VAF 199/807 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF469 | c.2315G>C p.G772A | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.031); called by muse, mutect2
- ZNF679 | c.262G>T p.V88F | Missense Mutation (SNP) | VAF 96/642 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- ZNF708 | c.1007A>T p.Y336F | Missense Mutation (SNP) | VAF 125/669 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- ZNF729 | c.145C>A p.L49M | Missense Mutation (SNP) | VAF 118/530 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- ZSCAN5C | c.82T>C p.S28P | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.675); called by muse, mutect2
- ZSWIM8 | c.3935C>A p.T1312K (on ENST00000605216 / NM_001242487.2; = p.T1317K on NM_015037.3) | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ABCC3 | c.228G>A p.L76= | Silent (SNP) | VAF 23/196 reads (12%) | catalogued as COSV53322058; called by muse, mutect2, varscan2
- ANKRD2 | c.129G>T p.A43= | Silent (SNP) | VAF 32/280 reads (11%) | called by muse, mutect2, varscan2
- ATP6AP1 | c.318C>T p.G106= | Silent (SNP) | VAF 47/766 reads (6%) | called by muse, mutect2
- AXL | c.762C>A p.P254= | Silent (SNP) | VAF 61/260 reads (23%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.2097G>T p.A699= (on ENST00000356253 / NM_001366867.1; = p.A687= on NM_000722.4) | Silent (SNP) | VAF 106/1126 reads (9%) | catalogued as COSV100666948, COSV62391410; called by muse, mutect2
- CARD11 | c.3138C>T p.A1046= | Silent (SNP) | VAF 28/310 reads (9%) | catalogued as rs753276102, COSV101210687, COSV67797893; called by muse, mutect2
- CCER1 | c.555G>T p.A185= | Silent (SNP) | VAF 55/347 reads (16%) | catalogued as COSV100726928; called by muse, mutect2, varscan2
- CDH12 | c.1170C>A p.T390= | Silent (SNP) | VAF 218/848 reads (26%) | catalogued as COSV66421598, COSV66429377; called by muse, mutect2, varscan2
- CFAP65 | c.432C>T p.G144= (on ENST00000341552 / NM_194302.4; = p.G79= on NM_152389.4) | Silent (SNP) | VAF 132/446 reads (30%) | called by muse, varscan2
- CSMD3 | c.5925T>A p.A1975= (on ENST00000297405 / NM_001363185.1; = p.A1871= on NM_052900.3) | Silent (SNP) | VAF 176/699 reads (25%) | called by muse, mutect2, varscan2
- CTNNAL1 | c.717C>G p.L239= | Silent (SNP) | VAF 90/419 reads (21%) | called by muse, mutect2, varscan2
- CTSL | c.726G>T p.V242= | Silent (SNP) | VAF 66/338 reads (20%) | called by muse, mutect2, varscan2
- DIAPH2 | c.1767G>A p.G589= | Silent (SNP) | VAF 24/394 reads (6%) | called by muse, mutect2
- DNAH7 | c.7689C>T p.Y2563= | Silent (SNP) | VAF 91/328 reads (28%) | catalogued as rs756612527; called by muse, mutect2, varscan2
- DSCAM | c.4150C>A p.R1384= | Silent (SNP) | VAF 107/547 reads (20%) | catalogued as rs376121987; called by muse, mutect2, varscan2
- FAM124A | c.327G>A p.E109= (on ENST00000322475 / NM_001242312.2; = p.E145= on NM_145019.4) | Silent (SNP) | VAF 26/250 reads (10%) | called by muse, mutect2, varscan2
- FAM170B | c.825C>G p.L275= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as rs979445435; called by muse, varscan2
- FAT3 | c.4026G>T p.T1342= | Silent (SNP) | VAF 31/337 reads (9%) | called by muse, mutect2, varscan2
- FEZF2 | c.783C>A p.G261= | Silent (SNP) | VAF 104/677 reads (15%) | called by muse, mutect2, varscan2
- FLNA | c.3918G>A p.E1306= | Silent (SNP) | VAF 35/368 reads (10%) | called by muse, mutect2
- FLNA | c.1287G>T p.T429= | Silent (SNP) | VAF 60/658 reads (9%) | called by muse, mutect2
- FLNC | c.7344G>A p.S2448= | Silent (SNP) | VAF 109/479 reads (23%) | catalogued as rs376251952; ClinVar: likely benign; called by muse, mutect2, varscan2
- FZD5 | c.1482G>T p.P494= | Silent (SNP) | VAF 157/493 reads (32%) | called by muse, mutect2, varscan2
- GDA | c.489G>T p.R163= | Silent (SNP) | VAF 90/430 reads (21%) | called by muse, varscan2
- GLI2 | c.3465G>T p.A1155= (on ENST00000361492 / NM_001374353.1; = p.A1172= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 93/309 reads (30%) | catalogued as COSV58048048; called by muse, mutect2, varscan2
- HOXA1 | c.945C>T p.S315= | Silent (SNP) | VAF 45/288 reads (16%) | catalogued as COSV58029328; called by muse, mutect2, varscan2
- IFNA16 | c.402G>T p.L134= | Silent (SNP) | VAF 98/498 reads (20%) | called by muse, mutect2, varscan2
- IL12RB1 | c.831C>G p.G277= | Silent (SNP) | VAF 140/508 reads (28%) | called by muse, mutect2, varscan2
- IRAK1 | c.1656C>A p.G552= | Silent (SNP) | VAF 63/353 reads (18%) | called by muse, mutect2, varscan2
- KCNA10 | c.1059G>A p.K353= | Silent (SNP) | VAF 46/646 reads (7%) | called by muse, mutect2
- KCNIP3 | c.630G>C p.A210= | Silent (SNP) | VAF 55/229 reads (24%) | called by muse, mutect2, varscan2
- KCNJ4 | c.1200C>A p.G400= | Silent (SNP) | VAF 71/469 reads (15%) | called by muse, mutect2, varscan2
- KCP | c.1245C>A p.P415= (on ENST00000620378; = p.P472= on NM_001366122.1) | Silent (SNP) | VAF 39/230 reads (17%) | called by muse, varscan2
- KCTD8 | c.267G>T p.L89= | Silent (SNP) | VAF 45/179 reads (25%) | called by muse, mutect2, varscan2
- KIF5A | c.2247C>T p.Y749= | Silent (SNP) | VAF 54/694 reads (8%) | catalogued as rs770805531, COSV54054991; ClinVar: likely benign; called by muse, mutect2
- KIRREL3 | c.1209C>A p.P403= | Silent (SNP) | VAF 64/375 reads (17%) | catalogued as COSV101375170, COSV69384303; called by muse, mutect2, varscan2
- KLF3 | c.441G>T p.P147= | Silent (SNP) | VAF 150/832 reads (18%) | called by muse, mutect2, varscan2
- KMT2D | c.7503G>C p.G2501= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs565210702; called by muse, mutect2, varscan2
- KRT31 | c.72C>A p.P24= | Silent (SNP) | VAF 86/393 reads (22%) | catalogued as COSV52434128; called by muse, mutect2, varscan2
- KRT35 | c.846G>C p.R282= | Silent (SNP) | VAF 38/217 reads (18%) | called by muse, mutect2, varscan2
- METTL17 | c.867T>A p.G289= | Silent (SNP) | VAF 56/322 reads (17%) | called by muse, varscan2
- MINDY2 | c.492G>T p.P164= | Silent (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- MINDY4B | c.669G>A p.V223= | Silent (SNP) | VAF 16/200 reads (8%) | catalogued as rs974690644; called by muse, mutect2
- MKI67 | c.585A>T p.A195= | Silent (SNP) | VAF 22/326 reads (7%) | called by muse, mutect2
- MNDA | c.348C>A p.P116= | Silent (SNP) | VAF 20/503 reads (4%) | catalogued as COSV63740784, COSV63742305; called by muse, mutect2
- MYH13 | c.2685C>A p.V895= | Silent (SNP) | VAF 65/302 reads (22%) | catalogued as COSV52838292; called by muse, mutect2, varscan2
- MYRIP | c.1221G>A p.L407= | Silent (SNP) | VAF 23/147 reads (16%) | catalogued as rs150509578; called by muse, mutect2, varscan2
- NHS | c.687C>T p.H229= | Silent (SNP) | VAF 50/476 reads (11%) | catalogued as rs754663070, COSV66279838; called by muse, mutect2, varscan2
- NTRK2 | c.1989C>A p.G663= (on ENST00000323115 / NM_001369534.1; = p.G679= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 81/571 reads (14%) | called by muse, mutect2, varscan2
- OLIG3 | c.126C>A p.S42= | Silent (SNP) | VAF 70/764 reads (9%) | called by muse, mutect2
- OR4S1 | c.429G>T p.A143= | Silent (SNP) | VAF 60/368 reads (16%) | called by muse, mutect2, varscan2
- OR5I1 | c.558G>A p.L186= | Silent (SNP) | VAF 17/190 reads (9%) | called by muse, mutect2
- OR5T1 | c.684C>A p.I228= | Silent (SNP) | VAF 54/737 reads (7%) | catalogued as COSV57301622; called by muse, mutect2
- PDIA4 | c.528A>G p.P176= | Silent (SNP) | VAF 55/456 reads (12%) | called by muse, mutect2, varscan2
- PGM5 | c.948C>A p.A316= | Silent (SNP) | VAF 56/1134 reads (5%) | called by muse, mutect2
- PRAG1 | c.3672G>T p.P1224= | Silent (SNP) | VAF 34/160 reads (21%) | called by muse, mutect2, varscan2
- PRAMEF2 | c.159G>T p.T53= | Silent (SNP) | VAF 90/582 reads (15%) | called by mutect2, varscan2
- PTCHD4 | c.1014C>A p.V338= | Silent (SNP) | VAF 90/595 reads (15%) | called by muse, varscan2
- RASSF10 | c.279C>T p.I93= | Silent (SNP) | VAF 64/385 reads (17%) | catalogued as rs1219766618; called by muse, mutect2, varscan2
- RHBDF2 | c.2349G>T p.L783= | Silent (SNP) | VAF 127/679 reads (19%) | called by muse, mutect2, varscan2
- RIT2 | c.495C>T p.A165= | Silent (SNP) | VAF 104/730 reads (14%) | catalogued as COSV100450044; called by muse, varscan2
- RNASEH1 | c.642G>T p.T214= | Silent (SNP) | VAF 51/187 reads (27%) | catalogued as COSV59439400; called by muse, mutect2, varscan2
- SCG3 | c.48G>A p.P16= | Silent (SNP) | VAF 62/579 reads (11%) | called by muse, mutect2, varscan2
- SETD1A | c.1371G>A p.R457= | Silent (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- SGO1 | c.1477C>T p.L493= (on ENST00000263753 / NM_001012410.5; = p.L224= on NM_138484.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/342 reads (15%) | called by muse, mutect2, varscan2
- SIAH3 | c.156C>A p.A52= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as COSV68551962; called by muse, mutect2, varscan2
- SLC4A5 | c.600G>C p.L200= | Silent (SNP) | VAF 66/233 reads (28%) | called by muse, mutect2, varscan2
- SLC5A9 | c.1626C>T p.A542= | Silent (SNP) | VAF 35/504 reads (7%) | catalogued as rs1256819672; called by muse, mutect2
- SPTB | c.2211G>A p.K737= | Silent (SNP) | VAF 92/853 reads (11%) | called by muse, mutect2, varscan2
- SUPT20HL2 | c.720G>A p.Q240= | Silent (SNP) | VAF 21/554 reads (4%) | called by muse, mutect2
- TARBP1 | c.831C>T p.D277= | Silent (SNP) | VAF 23/436 reads (5%) | called by muse, mutect2
- TATDN2 | c.48G>A p.S16= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs1176122411; called by muse, mutect2, varscan2
- TCHH | c.1956G>A p.Q652= | Silent (SNP) | VAF 36/446 reads (8%) | called by muse, mutect2
- TENT5C | c.945C>T p.N315= | Silent (SNP) | VAF 20/225 reads (9%) | catalogued as rs374139482; called by muse, mutect2
- THOP1 | c.522G>T p.L174= | Silent (SNP) | VAF 123/426 reads (29%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.2634G>T p.L878= | Silent (SNP) | VAF 268/1200 reads (22%) | called by muse, mutect2, varscan2
- TRBJ2-2 | c.18G>C p.L6= | Silent (SNP) | VAF 38/838 reads (5%) | called by muse, mutect2
- TRBJ2-2P | c.45G>T p.L15= | Silent (SNP) | VAF 22/99 reads (22%) | called by muse, mutect2, varscan2
- TRPC6 | c.1362G>T p.L454= | Silent (SNP) | VAF 83/822 reads (10%) | called by muse, mutect2, varscan2
- UNC79 | c.2847T>G p.L949= (on ENST00000393151 / NM_001346218.2; = p.L772= on NM_020818.5) | Silent (SNP) | VAF 15/381 reads (4%) | catalogued as COSV56382929; called by muse, mutect2
- VIP | c.294T>A p.S98= | Silent (SNP) | VAF 79/536 reads (15%) | called by muse, mutect2, varscan2
- VPS13D | c.2052C>T p.T684= | Silent (SNP) | VAF 63/461 reads (14%) | called by muse, mutect2, varscan2
- ZNF860 | c.234G>T p.A78= | Silent (SNP) | VAF 52/580 reads (9%) | called by muse, mutect2
- AAAS | c.399+87G>T | Intron (SNP) | VAF 14/240 reads (6%) | called by muse, mutect2
- ANXA2P2 | n.414G>T | RNA (SNP) | VAF 173/935 reads (19%) | called by muse, mutect2, varscan2
- APBA2 | c.*13dup | 3'UTR (INS) | VAF 72/375 reads (19%) | called by mutect2, pindel, varscan2
- AQP1 | c.*351C>T | 3'UTR (SNP) | VAF 14/94 reads (15%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+3655C>A | Intron (SNP) | VAF 27/196 reads (14%) | called by muse, mutect2, varscan2
- ATAD3B | c.*230G>C | 3'UTR (SNP) | VAF 36/521 reads (7%) | called by muse, mutect2
- BCAP31 | c.-44-342G>T | Intron (SNP) | VAF 66/240 reads (28%) | called by muse, mutect2, varscan2
- BEAN1 | chr16:66484789 C>A | 3'Flank (SNP) | VAF 66/511 reads (13%) | called by muse, mutect2, varscan2
- C1orf220 | n.256G>T | RNA (SNP) | VAF 99/335 reads (30%) | called by muse, mutect2, varscan2
- CABP7 | c.*1832C>A | 3'UTR (SNP) | VAF 49/342 reads (14%) | catalogued as COSV99334720; called by muse, varscan2
- CCL18 | c.*5C>A | 3'UTR (SNP) | VAF 40/183 reads (22%) | called by muse, mutect2, varscan2
- CELF4 | c.658-36G>A | Intron (SNP) | VAF 43/352 reads (12%) | called by muse, mutect2, varscan2
- CEP41 | chr7:130442419 A>T | 5'Flank (SNP) | VAF 25/315 reads (8%) | called by muse, mutect2
- CFLAR | c.523+187C>T | Intron (SNP) | VAF 244/929 reads (26%) | called by muse, mutect2, varscan2
- CLDND1 | c.-19+24C>T | Intron (SNP) | VAF 40/536 reads (7%) | called by muse, mutect2
- CPLANE1 | chr5:37245731 C>T | 5'Flank (SNP) | VAF 48/166 reads (29%) | called by muse, mutect2, varscan2
- CYYR1 | c.*8C>A | 3'UTR (SNP) | VAF 99/574 reads (17%) | catalogued as rs752414582; called by muse, mutect2, varscan2
- EEF1D | c.-7-3085A>G | Intron (SNP) | VAF 27/154 reads (18%) | called by muse, mutect2, varscan2
- ELAVL2 | c.-12-2815A>G | Intron (SNP) | VAF 73/404 reads (18%) | called by muse, mutect2, varscan2
- ENPP1 | c.556+24A>G | Intron (SNP) | VAF 131/786 reads (17%) | catalogued as rs755121158; called by muse, mutect2, varscan2
- FAM122C | c.345+2061A>C | Intron (SNP) | VAF 36/256 reads (14%) | called by muse, mutect2, varscan2
- FAM172BP | n.884C>A | RNA (SNP) | VAF 25/231 reads (11%) | called by muse, mutect2, varscan2
- FOXP2 | c.*674G>T | 3'UTR (SNP) | VAF 109/785 reads (14%) | called by muse, mutect2, varscan2
- GORAB | c.*656A>T | 3'UTR (SNP) | VAF 52/190 reads (27%) | called by muse, mutect2, varscan2
- HGF | c.865+459C>A | Intron (SNP) | VAF 139/782 reads (18%) | called by muse, mutect2, varscan2
- IFI27L2 | c.-2C>G | 5'UTR (SNP) | VAF 58/353 reads (16%) | called by muse, mutect2, varscan2
- KCNH3 | c.-45C>G | 5'UTR (SNP) | VAF 10/58 reads (17%) | called by muse, varscan2
- LINC00602 | n.1154C>A | RNA (SNP) | VAF 6/101 reads (6%) | called by muse, mutect2
- MAPK10 | c.1138+120G>A | Intron (SNP) | VAF 24/320 reads (8%) | catalogued as rs1019417376; called by muse, mutect2
- NARF | c.769+1123A>T | Intron (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- OR3A4P | n.614T>A | RNA (SNP) | VAF 133/413 reads (32%) | called by muse, mutect2, varscan2
- PDE10A | c.106+91598C>G | Intron (SNP) | VAF 12/235 reads (5%) | called by muse, mutect2
- PDPN | c.67+18T>A | Intron (SNP) | VAF 63/309 reads (20%) | called by muse, mutect2, varscan2
- POLN | c.1731+350G>T | Intron (SNP) | VAF 48/314 reads (15%) | called by muse, mutect2, varscan2
- PPM1E | c.*1916G>T | 3'UTR (SNP) | VAF 22/392 reads (6%) | called by muse, mutect2
- PRKAG2 | c.1005+17C>T | Intron (SNP) | VAF 74/540 reads (14%) | called by muse, mutect2, varscan2
- SERPINA9 | chr14:94476147 C>T | 5'Flank (SNP) | VAF 64/481 reads (13%) | catalogued as rs762911599; called by muse, mutect2, varscan2
- SERPINA9 | chr14:94476202 G>A | 5'Flank (SNP) | VAF 89/754 reads (12%) | called by muse, mutect2, varscan2
- SHISA8 | chr22:41909948 G>T | 3'Flank (SNP) | VAF 20/115 reads (17%) | called by muse, mutect2, varscan2
- SLC22A11 | c.1058+51G>T | Intron (SNP) | VAF 50/249 reads (20%) | called by muse, mutect2, varscan2
- SLC25A48-AS1 | n.28C>A | RNA (SNP) | VAF 45/324 reads (14%) | called by muse, mutect2, varscan2
- SNORD116-24 | n.51G>T | RNA (SNP) | VAF 55/498 reads (11%) | called by muse, mutect2, varscan2
- SPAG5 | c.177+45G>A | Intron (SNP) | VAF 55/259 reads (21%) | catalogued as rs933722798; called by muse, mutect2, varscan2
- SPATA31C1 | n.834C>T | RNA (SNP) | VAF 101/519 reads (19%) | called by mutect2, varscan2
- TMEM132D | c.1444-48del | Intron (DEL) | VAF 15/64 reads (23%) | called by mutect2, pindel, varscan2
- TMEM273 | c.43+10037C>G | Intron (SNP) | VAF 46/380 reads (12%) | catalogued as rs1324570916; called by muse, mutect2, varscan2
- UQCRB | c.*118G>A | 3'UTR (SNP) | VAF 93/327 reads (28%) | called by muse, mutect2, varscan2
- VSX1 | chr20:25071313 T>C | 3'Flank (SNP) | VAF 58/149 reads (39%) | called by muse, mutect2, varscan2
- ZIC4 | c.-16+874A>G | Intron (SNP) | VAF 95/1064 reads (9%) | called by muse, mutect2
- ZIC4 | c.-16+873G>T | Intron (SNP) | VAF 94/1060 reads (9%) | called by muse, mutect2
